Somatic mutation profile of tumor specimen RC-B56E-TTP1-A (aliquot RC-B56E-TTP1-A-1-1-D-A93N-47) from RC case RC-B56E, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: male; Vital status: Alive; Primary diagnosis: Anaplastic large cell lymphoma, ALK negative; Tissue or organ of origin: Lymph node, NOS; Age at diagnosis: 77.8 years (28,427 days).
Specimen RC-B56E-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7798477a-9be8-47e8-b09b-af3d5264859e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen RC-B56E-NB1-A (Granulocytes; tissue type Normal), aliquot RC-B56E-NB1-A-1-0-D-A93N-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d965c23f-8bdb-41e7-82f5-4e6a8fbc2ede

The open-access MAF lists 426 somatic variants for this specimen: 284 protein-altering or splice-affecting, 119 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 250, Silent 119, Nonsense Mutation 17, Intron 11, Splice Region 7, RNA 6, Frame Shift Del 5, In Frame Del 3, 5'UTR 2, 3'UTR 2, 5'Flank 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.5140G>A p.E1714K | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.046); catalogued as COSV70027374, COSV70028617; called by muse, mutect2, varscan2
- ABCC6 | c.1879G>A p.D627N | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT tolerated (0.7); PolyPhen benign (0.209); catalogued as rs1466190573, COSV52741687; called by muse, mutect2, varscan2
- ADAM17 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as rs1221596363, COSV100176465; called by muse, mutect2, varscan2
- ADAMTS10 | c.842G>A p.G281E | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99546345; called by muse, mutect2, varscan2
- ADAMTS12 | c.2267G>A p.G756E | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV61263232, COSV61272776; called by muse, mutect2, varscan2
- ADCY2 | c.3200G>A p.G1067E | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100604182; called by muse, mutect2, varscan2
- ADGRA1 | c.737G>A p.G246E | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as rs754831989; called by muse, mutect2, varscan2
- ADGRF3 | c.1978C>T p.R660* (on ENST00000311519 / NM_001145168.1; = p.R461* on NM_153835.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 45/127 reads (35%) | catalogued as rs116734873; called by muse, mutect2, varscan2
- AKAP6 | c.5170C>T p.R1724C | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs144252079; called by muse, mutect2, varscan2
- AMPD2 | c.1457G>T p.R486L | Missense Mutation (SNP) | VAF 51/153 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM150813; called by muse, mutect2, varscan2
- ANAPC1 | c.2965G>A p.E989K | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs1267075110; called by mutect2, varscan2
- ANHX | c.766G>A p.G256R | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs1271810788; called by muse, mutect2, varscan2
- ANKRD30B | c.3514G>A p.E1172K | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.908); catalogued as COSV100271456; called by muse, mutect2, varscan2
- AP1B1 | c.1564C>T p.R522C | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1245595086, COSV100434853; called by muse, mutect2, varscan2
- ARHGEF17 | c.1303C>T p.R435C | Missense Mutation (SNP) | VAF 56/153 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.959); catalogued as rs1488147269, COSV99735933; called by muse, mutect2, varscan2
- ARNT2 | c.1939G>A p.G647R | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.361); catalogued as rs566627231, COSV100308669, COSV57591920; called by muse, mutect2, varscan2
- ASTN2 | c.1527G>A p.W509* (on ENST00000313400 / NM_001365069.1; = p.W458* on NM_014010.5) | Nonsense Mutation (SNP) | VAF 34/94 reads (36%) | catalogued as COSV57761560; called by muse, mutect2, varscan2
- ATG7 | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.255); catalogued as COSV61610841; called by muse, mutect2, varscan2
- B3GNTL1 | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 59/162 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV57953577; called by muse, mutect2, varscan2
- B3GNTL1 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 60/163 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.604); catalogued as COSV57948674, COSV57951299; called by muse, mutect2, varscan2
- C12orf43 | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 31/127 reads (24%) | catalogued as rs781267553; called by muse, mutect2, varscan2
- C2CD4C | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 53/130 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as rs1189077275; called by muse, mutect2, varscan2
- C9orf135 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1267122393; called by muse, mutect2
- CCDC122 | c.92C>A p.A31E | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs78953797; called by muse, mutect2
- CCDC154 | c.1823C>T p.P608L | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs746911929; called by muse, mutect2
- CCDC154 | c.1822C>T p.P608S | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs993143622; called by muse, mutect2
- CCDC171 | c.298C>T p.R100W | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.481); catalogued as rs142125441; called by muse, mutect2, varscan2
- CCDC178 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV55765767; called by muse, mutect2, varscan2
- CDH11 | c.1663G>T p.A555S | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV51761665, COSV51776760; called by muse, mutect2, varscan2
- CDH6 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as COSV54072056; called by muse, mutect2, varscan2
- CEP112 | c.1580G>A p.R527K | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.875); catalogued as COSV67138101; called by muse, mutect2
- COL18A1 | c.5105C>T p.T1702I (on ENST00000359759 / NM_130444.3; = p.T1467I on NM_030582.4) | Missense Mutation (SNP) | VAF 60/167 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.324); catalogued as rs1568957123; called by muse, mutect2, varscan2
- COL5A2 | c.2156G>A p.R719K | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as rs760537680; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CORIN | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.559); catalogued as COSV56685474; called by muse, mutect2, varscan2
- CRACR2B | c.694-5C>T | Splice Region (SNP) | VAF 79/204 reads (39%) | catalogued as rs1421816359; called by muse, mutect2, varscan2
- CSMD1 | c.7514G>A p.G2505D (on ENST00000520002; = p.G2504D on NM_033225.6) | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1343790235, COSV99045816; called by muse, mutect2
- CWH43 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs755347963, COSV99893684; called by muse, mutect2, varscan2
- DCLK3 | c.1675G>A p.D559N | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.627); catalogued as COSV101373976, COSV69365030; called by muse, mutect2, varscan2
- DDX31 | c.215G>T p.R72M | Missense Mutation (SNP) | VAF 71/174 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.831); catalogued as COSV60135982; called by muse, mutect2, varscan2
- DISP2 | c.899G>A p.W300* | Nonsense Mutation (SNP) | VAF 26/81 reads (32%) | catalogued as COSV99140067; called by muse, mutect2, varscan2
- DNAH3 | c.2200G>A p.A734T | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756543294; called by muse, mutect2, varscan2
- DSCAM | c.4003C>T p.R1335W | Missense Mutation (SNP) | VAF 58/147 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752819720, COSV101258904, COSV68020104; called by muse, mutect2, varscan2
- DSCAM | c.2194C>T p.P732S | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.433); catalogued as COSV68036089; called by muse, mutect2, varscan2
- DSG1 | c.1732C>T p.R578C | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.443); catalogued as rs868433988, COSV57135599, COSV99062424; called by muse, mutect2, varscan2
- DYRK1B | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV55684147; called by muse, mutect2, varscan2
- ETFBKMT | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as COSV100740338; called by muse, mutect2, varscan2
- FAM135A | c.2782G>A p.E928K (on ENST00000370479 / NM_001351599.1; = p.E715K on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs375463366; called by muse, mutect2, varscan2
- FAM25A | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 61/172 reads (35%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.054); catalogued as rs767640778; called by muse, mutect2, varscan2
- FAT4 | c.8142G>A p.M2714I | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV58673280; called by muse, mutect2, varscan2
- FBLN5 | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.749); catalogued as COSV50902110; called by muse, mutect2, varscan2
- FGF14 | c.564G>T p.K188N | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65956986; called by mutect2, varscan2
- FKBP10 | c.677G>A p.R226K | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs556997852; called by muse, mutect2, varscan2
- FLG | c.521G>A p.G174E | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as rs1194239166, COSV64239899; called by muse, mutect2, varscan2
- FLNC | c.6610G>A p.E2204K | Missense Mutation (SNP) | VAF 62/145 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0.058); catalogued as rs1476564683; called by muse, mutect2, varscan2
- FRMPD4 | c.3593G>A p.R1198Q | Missense Mutation (SNP) | VAF 54/76 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.856); catalogued as rs376320353, COSV66212003; called by muse, mutect2, varscan2
- GALNT13 | c.687G>A p.R229= | Splice Region (SNP) | VAF 26/75 reads (35%) | catalogued as rs267598929, COSV67214648; called by muse, mutect2, varscan2
- GALNT17 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 52/153 reads (34%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.709); catalogued as rs866308070, COSV100355048, COSV61148982; called by muse, mutect2, varscan2
- GASK1B | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 58/176 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.613); catalogued as rs764308392; called by muse, mutect2, varscan2
- GPRC6A | c.992G>A p.G331E | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); catalogued as rs748301096; called by muse, mutect2, varscan2
- GPRIN1 | c.2083G>A p.D695N | Missense Mutation (SNP) | VAF 18/189 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1351072330; called by muse, mutect2
- HID1 | c.69C>T p.P23= | Splice Region (SNP) | VAF 29/95 reads (31%) | catalogued as rs762368807, COSV59351141; called by muse, mutect2, varscan2
- HNF4G | c.844C>T p.R282W (on ENST00000354370 / NM_001330561.2; = p.R329W on NM_004133.5) | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1483199309, COSV62972046; called by muse, mutect2, varscan2
- HSPA8 | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.672); catalogued as COSV99914358; called by muse, mutect2, varscan2
- ILDR1 | c.704G>A p.G235E | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56552981; called by muse, mutect2, varscan2
- ITGB4 | c.2781G>A p.Q927= | Splice Region (SNP) | VAF 39/125 reads (31%) | catalogued as COSV99563977; called by muse, mutect2, varscan2
- ITK | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 65/146 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70065884; called by muse, mutect2, varscan2
- KAT6B | c.2878C>T p.R960W | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs147643220; called by muse, mutect2, varscan2
- KCND2 | c.1865G>A p.G622E | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.035); catalogued as COSV58573780; called by muse, mutect2, varscan2
- KIAA1755 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.08); catalogued as COSV54073304, COSV54077048; called by muse, mutect2, varscan2
- KMO | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866195768; called by muse, mutect2, varscan2
- KNG1 | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.321); catalogued as COSV53976030, COSV53977930; called by muse, mutect2, varscan2
- LENG9 | c.997G>A p.V333M | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV100002875; called by muse, mutect2, varscan2
- LRCH2 | c.1324C>T p.R442W | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as rs1474593682; called by muse, mutect2, varscan2
- LRP5 | c.1348C>T p.R450C | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765695793, COSV99592181; called by muse, mutect2, varscan2
- LRRC55 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV73006615; called by muse, mutect2, varscan2
- MEP1B | c.801T>A p.F267L | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52499439; called by muse, mutect2, varscan2
- MMP3 | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as rs782395032, COSV55408499; called by muse, mutect2, varscan2
- MYO16 | c.31C>T p.L11F | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752075568; called by muse, mutect2, varscan2
- MYO7B | c.781G>A p.G261R | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769470626; called by muse, mutect2, varscan2
- NAALADL1 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as rs1399029809; called by muse, mutect2, varscan2
- NAT10 | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147022056; called by muse, mutect2, varscan2
- NCBP3 | c.76C>A p.P26T | Missense Mutation (SNP) | VAF 69/169 reads (41%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.034); catalogued as rs1470929726; called by muse, mutect2, varscan2
- NPTXR | c.1126G>A p.D376N | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755066146; called by muse, mutect2, varscan2
- OLFML2B | c.1303C>T p.P435S | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0.037); catalogued as rs746506579; called by muse, mutect2, varscan2
- OR1E2 | c.16C>T p.Q6* | Nonsense Mutation (SNP) | VAF 36/110 reads (33%) | catalogued as rs911781660; called by muse, mutect2
- OR2T3 | c.953A>G p.K318R | Missense Mutation (SNP) | VAF 41/240 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.134); catalogued as rs1236780397, COSV62082901; called by muse, mutect2, varscan2
- OR6C1 | c.937T>G p.*313Gext*5 | Nonstop Mutation (SNP) | VAF 28/66 reads (42%) | catalogued as COSV101110505; called by muse, mutect2, varscan2
- PAX8 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.457); catalogued as rs919587560, COSV99638956; called by muse, mutect2, varscan2
- PCDH15 | c.4918G>A p.E1640K | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT deleterious, low confidence (0.01); catalogued as COSV64692257; called by muse, mutect2, varscan2
- PCDHGA5 | c.1396C>T p.P466S | Missense Mutation (SNP) | VAF 60/120 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.728); catalogued as rs1266306756, COSV53976166; called by muse, mutect2, varscan2
- PCDHGB5 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.582); catalogued as rs1180861423; called by muse, mutect2, varscan2
- PDE6C | c.362C>T p.S121F | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65116525; called by muse, mutect2, varscan2
- PLXNA1 | c.5206G>A p.V1736M | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1416770783, COSV99078723; called by muse, mutect2, varscan2
- PPP1R16A | c.223C>T p.L75F | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as COSV52952723; called by muse, mutect2, varscan2
- PRAME | c.758C>T p.S253F | Missense Mutation (SNP) | VAF 53/130 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.325); catalogued as COSV67161476; called by muse, mutect2, varscan2
- PRICKLE2 | c.2428G>A p.D810N (on ENST00000295902; = p.D754N on NM_198859.4) | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.159); catalogued as COSV55770850; called by muse, mutect2, varscan2
- PSMA7 | c.712_714del p.E238del | In Frame Del (DEL) | VAF 24/83 reads (29%) | catalogued as rs1460675536; called by pindel, varscan2
- PTPN9 | c.1325A>G p.Y442C | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777730659; called by muse, mutect2, varscan2
- PUS7 | c.1193C>T p.S398F | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as COSV62676461, COSV62678589; called by muse, mutect2, varscan2
- PYROXD2 | c.1682G>A p.G561D | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV65330795; called by muse, mutect2, varscan2
- RANBP17 | c.3083C>T p.P1028L | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as rs747581808; called by muse, mutect2, varscan2
- RARA | c.1181G>A p.R394Q | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs866777491, COSV54191573, COSV54196311; called by muse, mutect2, varscan2
- RBFOX2 | c.1072C>T p.R358* (on ENST00000438146 / NM_001349995.2; = p.R284* on NM_014309.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 26/147 reads (18%) | catalogued as COSV53266032; called by muse, mutect2, varscan2
- RBM6 | c.1196C>T p.T399I | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV99805504; called by muse, mutect2, varscan2
- RBMXL3 | c.1991G>A p.G664E | Missense Mutation (SNP) | VAF 101/143 reads (71%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as rs1556559328; called by muse, mutect2, varscan2
- RGSL1 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.17); catalogued as rs748623780, COSV54256759; called by muse, mutect2, varscan2
- RNF149 | c.591C>G p.S197R | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.879); catalogued as COSV54864784; called by muse, mutect2, varscan2
- RP1L1 | c.6074C>T p.A2025V | Missense Mutation (SNP) | VAF 65/203 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.063); catalogued as rs751636089; called by muse, mutect2, varscan2
- RUFY4 | c.1135G>A p.G379R | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as rs186181747; called by muse, mutect2, varscan2
- SAMD13 | c.142C>T p.P48S (on ENST00000370671; = p.P42S on NM_001010971.3) | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as COSV65744766; called by muse, mutect2, varscan2
- SBK3 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as rs1268193491; called by muse, mutect2, varscan2
- SCN7A | c.898G>A p.G300R | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV69273455; called by muse, mutect2, varscan2
- SLC26A9 | c.971C>T p.S324L | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769381035, COSV61602420; called by muse, mutect2, varscan2
- SLC7A14 | c.1534G>A p.G512S | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs139104563; called by muse, mutect2, varscan2
- SLITRK6 | c.2179C>T p.H727Y | Missense Mutation (SNP) | VAF 47/144 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.026); catalogued as COSV68390891; called by muse, mutect2, varscan2
- SPAG17 | c.2971G>A p.E991K | Missense Mutation (SNP) | VAF 53/141 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.548); catalogued as rs772886823, COSV60468530; called by muse, mutect2, varscan2
- SPHKAP | c.491G>A p.R164K | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.081); catalogued as rs1198782318, COSV60873447; called by muse, mutect2, varscan2
- SVOPL | c.1318C>T p.R440C (on ENST00000419765; = p.R288C on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs780045890, COSV55988346; called by muse, mutect2
- SYT1 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as rs763002892, COSV54034212; called by muse, mutect2, varscan2
- TAAR8 | c.787G>C p.V263L | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as COSV51586822; called by muse, mutect2, varscan2
- TACC2 | c.2456C>T p.S819F | Missense Mutation (SNP) | VAF 55/163 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as COSV57770008; called by muse, mutect2, varscan2
- TBRG4 | c.1472C>T p.P491L | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.109); catalogued as rs1179481218, COSV51831853; called by muse, mutect2, varscan2
- TKTL2 | c.1498C>T p.R500C | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.117); catalogued as rs961660795, COSV54918377; called by muse, mutect2, varscan2
- TLR5 | c.731G>A p.G244E | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0.152); catalogued as COSV60559127; called by muse, mutect2, varscan2
- TMEM174 | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1309102620; called by muse, mutect2, varscan2
- TMPRSS3 | c.827C>T p.S276F | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV52304183; called by muse, mutect2, varscan2
- TTN | c.40653G>A p.M13551I (on ENST00000591111; = p.M6127I on NM_003319.4) | Missense Mutation (SNP) | VAF 30/103 reads (29%) | PolyPhen benign (0.007); catalogued as rs1559876731; called by muse, mutect2, varscan2
- ULK4 | c.2512C>T p.Q838* | Nonsense Mutation (SNP) | VAF 40/118 reads (34%) | catalogued as rs1265880372; called by muse, mutect2
- UNC13B | c.4520C>T p.S1507F | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.438); catalogued as COSV100266746; called by muse, mutect2, varscan2
- USH2A | c.8089G>A p.E2697K | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.357); catalogued as COSV56413558; called by muse, mutect2, varscan2
- VWA2 | c.1831G>A p.G611S | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs377210274; called by muse, mutect2, varscan2
- ZAN | c.6166G>A p.E2056K | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV61809232; called by muse, mutect2, varscan2
- ZNF445 | c.2199G>A p.M733I | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV68538738; called by muse, mutect2, varscan2
- ZNF568 | c.1706G>A p.R569Q | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.086); catalogued as rs767853902, COSV61742790; called by muse, mutect2, varscan2
- ZNF701 | c.757C>T p.R253C (on ENST00000301093; = p.R187C on NM_018260.3) | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs1488832293, COSV56524533; called by muse, mutect2, varscan2
- A2ML1 | c.160G>A p.V54I | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.02); called by muse, varscan2
- ACTG2 | c.565T>A p.Y189N | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- ADAM17 | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ADAMTS2 | c.2359A>T p.T787S | Missense Mutation (SNP) | VAF 52/115 reads (45%) | SIFT tolerated (0.74); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADGB | c.1627T>A p.L543I | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- ADGRA3 | c.2281C>T p.P761S | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRB1 | c.2357T>C p.F786S | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- AFF2 | c.3071C>T p.S1024F | Missense Mutation (SNP) | VAF 41/62 reads (66%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AHNAK2 | c.13582G>A p.D4528N | Missense Mutation (SNP) | VAF 81/238 reads (34%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- AKNAD1 | c.1529C>T p.S510L | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ARHGEF38 | c.872T>C p.L291S | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- ARNT2 | c.1940G>A p.G647E | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- BBOX1 | c.1042G>T p.G348C | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BICRAL | c.1870C>T p.P624S | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- BICRAL | c.1871C>T p.P624L | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- BORCS8 | c.350C>T p.S117F | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- BTAF1 | c.263C>G p.S88C | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- C3 | c.4642C>T p.R1548* | Nonsense Mutation (SNP) | VAF 18/35 reads (51%) | called by muse, mutect2, varscan2
- C9orf116 | c.192del p.S65Afs*44 (on ENST00000429260 / NM_001048265.2; = p.S65Afs*33 on NM_144654.3) | Frame Shift Del (DEL) | VAF 41/127 reads (32%) | called by mutect2, pindel, varscan2
- CCDC105 | c.1180G>A p.D394N | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CCDC122 | c.94A>G p.K32E | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.79); PolyPhen benign (0.013); called by muse, mutect2
- CCDC179 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CCT5 | c.1250G>T p.R417L | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- CEMIP | c.3841G>A p.A1281T | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CHCHD3 | c.564_574del p.K189Vfs*4 | Frame Shift Del (DEL) | VAF 40/91 reads (44%) | called by mutect2, pindel, varscan2
- CLDN22 | c.138G>A p.W46* | Nonsense Mutation (SNP) | VAF 64/173 reads (37%) | called by muse, mutect2, varscan2
- COL11A1 | c.4093C>T p.P1365S | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- COL4A5 | c.2972G>A p.G991E | Missense Mutation (SNP) | VAF 41/63 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL7A1 | c.6065G>A p.G2022E | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.599); called by muse, varscan2
- CRACD | c.1055G>A p.G352E | Missense Mutation (SNP) | VAF 56/186 reads (30%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2
- CREB3 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYB5R3 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- CYP4A22 | c.129G>A p.W43* | Nonsense Mutation (SNP) | VAF 39/129 reads (30%) | called by muse, mutect2, varscan2
- DGKB | c.1364T>C p.I455T | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.543); called by muse, mutect2
- DHTKD1 | c.1924G>A p.A642T | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- DNAH11 | c.2607G>T p.L869F | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- DNAH11 | c.5622G>A p.R1874= | Splice Region (SNP) | VAF 20/56 reads (36%) | called by muse, mutect2, varscan2
- DOCK11 | c.5300C>T p.A1767V | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- EGF | c.2870C>T p.P957L | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ELMO3 | c.1283C>T p.S428F (on ENST00000652269; = p.S375F on NM_024712.5) | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- EPB42 | c.664C>T p.L222F (on ENST00000441366 / NM_001114134.2; = p.L252F on NM_000119.3) | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT tolerated (0.7); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- FAM47C | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 75/97 reads (77%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- FAM83F | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT tolerated (0.75); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- FBN1 | c.7220A>G p.K2407R | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.78); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- FOXI3 | c.738T>A p.N246K | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FRMPD3 | c.5114C>T p.T1705I | Missense Mutation (SNP) | VAF 43/68 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- GASK1A | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 56/146 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- GDPD5 | c.920G>T p.R307I | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- GRIK1 | c.1946G>A p.R649K | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- GRIP1 | c.283C>A p.L95M | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GSG1L2 | c.473G>A p.R158K | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HCRTR2 | c.497C>A p.A166E | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- HNRNPDL | c.1240C>T p.Q414* | Nonsense Mutation (SNP) | VAF 34/100 reads (34%) | called by muse, mutect2, varscan2
- HS3ST3A1 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- HYDIN | c.13742T>G p.I4581S | Missense Mutation (SNP) | VAF 63/87 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- HYDIN | c.12721C>T p.Q4241* | Nonsense Mutation (SNP) | VAF 28/58 reads (48%) | called by muse, mutect2, varscan2
- IQCA1 | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- ITGA5 | c.966G>T p.M322I | Missense Mutation (SNP) | VAF 55/146 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ITGAM | c.830G>A p.R277K | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KALRN | c.8635C>T p.P2879S (on ENST00000360013 / NM_001024660.4; = p.P1182S on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNT2 | c.2510C>T p.T837I | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- KIF1C | c.1381A>G p.K461E | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- KRT77 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- KRTAP9-4 | c.55T>G p.C19G | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- LCE2B | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- LRRC36 | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- LYST | c.5261C>T p.T1754I | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- LYST | c.2390G>T p.C797F | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- MAGEB3 | c.893C>T p.T298I | Missense Mutation (SNP) | VAF 56/73 reads (77%) | SIFT deleterious (0.02); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- MAPK7 | c.386A>G p.E129G | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- MED13 | c.6285T>A p.F2095L | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MEFV | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MROH7 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); called by muse, mutect2
- MSC | c.262_263dup p.G89Afs*36 | Frame Shift Ins (INS) | VAF 26/146 reads (18%) | called by mutect2, pindel, varscan2
- MSTO1 | c.1570G>C p.A524P | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.445); called by muse, mutect2
- MT1E | c.179G>T p.C60F | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- MUC16 | c.22387G>A p.E7463K | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- MUC16 | c.20240C>T p.S6747L | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- MYBPHL | c.1015C>G p.L339V | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- MYO1B | c.3216A>T p.E1072D (on ENST00000304164; = p.E1014D on NM_012223.5) | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYT1 | c.1407G>T p.K469N | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAGLU | c.1813G>A p.A605T | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NAV3 | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NBPF26 | c.1305T>A p.D435E (on ENST00000620612; = p.D173E on NM_001351372.1) | Missense Mutation (SNP) | VAF 47/177 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- NFATC4 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- NIPBL | c.2849C>T p.S950F | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- NUTM2A | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- OCA2 | c.1165G>C p.A389P | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- OR10AC1 | c.724C>T p.R242C | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious, low confidence (0); called by muse, varscan2
- OR14A2 | c.14C>T p.T5I | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- PARM1 | c.560C>A p.T187N | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.55); called by muse, mutect2
- PAXIP1 | c.296T>C p.F99S | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDH7 | c.2715A>T p.K905N | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- PCDH8 | c.971T>C p.V324A | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); called by muse, mutect2
- PCDHGB4 | c.1835C>T p.P612L | Missense Mutation (SNP) | VAF 42/195 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- PLEKHG4B | c.2537G>A p.G846E (on ENST00000283426; = p.G1202E on NM_052909.5) | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLXNB1 | c.3322G>A p.V1108M | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PNPLA1 | c.1408A>T p.K470* (on ENST00000394571 / NM_001374623.1; = p.K375* on NM_173676.2) | Nonsense Mutation (SNP) | VAF 35/90 reads (39%) | called by muse, mutect2, varscan2
- POLE | c.910G>A p.G304S | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- POT1 | c.1450_1482del p.E484_I494del | In Frame Del (DEL) | VAF 18/63 reads (29%) | called by mutect2, pindel, varscan2
- PPP1R10 | c.2737C>T p.R913* | Nonsense Mutation (SNP) | VAF 12/172 reads (7%) | called by muse, mutect2
- PRPF38B | c.1009_1020del p.S340_R343del | In Frame Del (DEL) | VAF 31/119 reads (26%) | called by mutect2, pindel, varscan2
- PTPRO | c.1599A>G p.I533M | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- PTPRS | c.3511A>C p.T1171P | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- PVALEF | c.27G>A p.M9I | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- REG1A | c.320del p.K107Rfs*32 | Frame Shift Del (DEL) | VAF 26/112 reads (23%) | called by mutect2, pindel, varscan2
- RHBDD1 | c.16A>G p.R6G | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- RORB | c.153C>A p.N51K (on ENST00000396204 / NM_001365023.1; = p.N40K on NM_006914.4) | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- RRAGD | c.347G>T p.W116L | Missense Mutation (SNP) | VAF 54/138 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RTP5 | c.1516C>T p.Q506* | Nonsense Mutation (SNP) | VAF 24/208 reads (12%) | called by muse, mutect2, varscan2
- RUNDC1 | c.1300G>T p.V434L | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SCYGR7 | c.5G>A p.G2D | Missense Mutation (SNP) | VAF 46/143 reads (32%) | called by muse, mutect2, varscan2
- SDK1 | c.4747G>A p.G1583R | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SEMA4B | c.1037C>T p.S346F | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SERPINB13 | c.823C>A p.H275N | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- SFMBT2 | c.91C>T p.L31F | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- SIRPA | c.833T>C p.F278S | Missense Mutation (SNP) | VAF 65/177 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC29A4 | c.940_947del p.E314Rfs*10 | Frame Shift Del (DEL) | VAF 41/139 reads (29%) | called by mutect2, pindel, varscan2
- SLC6A17 | c.2010C>G p.N670K | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT tolerated (0.72); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- SLC7A14 | c.1535G>A p.G512D | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC8A3 | c.2240C>T p.P747L (on ENST00000381269 / NM_183002.3; = p.P745L on NM_033262.4) | Missense Mutation (SNP) | VAF 54/174 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC9A2 | c.1064C>T p.S355F | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPAG17 | c.6583G>A p.G2195R | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- SPATA31A3 | c.772G>T p.E258* | Nonsense Mutation (SNP) | VAF 46/175 reads (26%) | called by muse, mutect2, varscan2
- SPDYE5 | c.204G>A p.W68* | Nonsense Mutation (SNP) | VAF 40/111 reads (36%) | called by muse, mutect2, varscan2
- SPO11 | c.875G>A p.G292E | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPTBN1 | c.6371G>A p.G2124E | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (0.72); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SRSF3 | c.202G>A p.G68R | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- SRSF3 | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SYK | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TBC1D30 | c.1754T>A p.L585Q (on ENST00000542120; = p.L422Q on NM_015279.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- TCERG1L | c.475A>T p.I159F | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- TCF7 | c.689C>A p.A230D | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- TMEM143 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- TNXB | c.1201G>T p.V401L | Missense Mutation (SNP) | VAF 86/225 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- TONSL | c.2894C>T p.A965V | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- TRBV5-1 | c.31C>T p.L11F | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- TRIM51 | c.421C>A p.L141I | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- TRIM69 | c.57G>A p.M19I | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- TSG101 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- TSG101 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- VPS13C | c.8550G>A p.L2850= (on ENST00000644861 / NM_020821.3; = p.L2807= on NM_017684.5) | Splice Region (SNP) | VAF 21/78 reads (27%) | called by muse, mutect2, varscan2
- WDR3 | c.181C>T p.L61F | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- Z83844.2 | c.1589_1604del p.C530Sfs*27 | Frame Shift Del (DEL) | VAF 33/127 reads (26%) | called by mutect2, pindel, varscan2
- ZBTB49 | c.948G>C p.K316N | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- ZDHHC18 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by mutect2, varscan2
- ZIM3 | c.240A>C p.A80= | Splice Region (SNP) | VAF 40/98 reads (41%) | called by muse, mutect2, varscan2
- ZNF117 | c.754G>C p.E252Q | Missense Mutation (SNP) | VAF 61/146 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- ZNF610 | c.1343A>T p.K448I | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- AC099489.1 | c.6198G>A p.G2066= | Silent (SNP) | VAF 37/106 reads (35%) | called by muse, mutect2
- ACSM4 | c.177G>C p.L59= | Silent (SNP) | VAF 17/62 reads (27%) | called by muse, mutect2, varscan2
- ADAMTS13 | c.1518C>T p.T506= | Silent (SNP) | VAF 45/144 reads (31%) | called by muse, mutect2, varscan2
- AGAP5 | c.1915C>T p.L639= | Silent (SNP) | VAF 65/200 reads (33%) | called by muse, mutect2, varscan2
- AHNAK2 | c.13581G>A p.V4527= | Silent (SNP) | VAF 79/234 reads (34%) | called by muse, varscan2
- AK9 | c.2322C>T p.V774= | Silent (SNP) | VAF 28/82 reads (34%) | catalogued as rs1246399631, COSV58141345; called by muse, mutect2, varscan2
- ALDH1L1 | c.222G>A p.Q74= | Silent (SNP) | VAF 45/123 reads (37%) | catalogued as COSV56410034; called by muse, mutect2, varscan2
- ANK2 | c.3288C>T p.V1096= | Silent (SNP) | VAF 42/135 reads (31%) | called by muse, mutect2, varscan2
- AP1B1 | c.1563C>T p.D521= | Silent (SNP) | VAF 36/75 reads (48%) | called by muse, mutect2, varscan2
- APOB | c.12111C>T p.T4037= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as rs1018981649; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGEF17 | c.1302C>T p.T434= | Silent (SNP) | VAF 56/154 reads (36%) | called by muse, mutect2, varscan2
- BSN | c.7704A>T p.L2568= | Silent (SNP) | VAF 47/139 reads (34%) | called by muse, mutect2, varscan2
- CCDC105 | c.1179G>A p.L393= | Silent (SNP) | VAF 34/112 reads (30%) | called by muse, mutect2, varscan2
- CHRNB4 | c.315C>T p.I105= | Silent (SNP) | VAF 23/78 reads (29%) | called by muse, mutect2, varscan2
- CPNE8 | c.369C>T p.I123= | Silent (SNP) | VAF 37/114 reads (32%) | catalogued as rs754895189, COSV58838819, COSV58853185; called by muse, mutect2, varscan2
- CTH | c.474C>T p.T158= | Silent (SNP) | VAF 27/88 reads (31%) | catalogued as rs897545497; called by muse, mutect2, varscan2
- CYB5R3 | c.834C>T p.P278= | Silent (SNP) | VAF 45/141 reads (32%) | catalogued as rs767766639; called by muse, mutect2, varscan2
- DCAF8L1 | c.432C>T p.S144= | Silent (SNP) | VAF 60/85 reads (71%) | called by muse, mutect2, varscan2
- DOCK4 | c.1656C>T p.F552= | Silent (SNP) | VAF 56/150 reads (37%) | catalogued as COSV70233636, COSV70234757; called by muse, mutect2, varscan2
- EHBP1 | c.3552C>T p.A1184= | Silent (SNP) | VAF 20/113 reads (18%) | catalogued as rs752290565; called by muse, mutect2, varscan2
- ERBB4 | c.12G>A p.A4= | Silent (SNP) | VAF 48/136 reads (35%) | catalogued as rs779335121; called by muse, mutect2, varscan2
- FAT4 | c.3069G>A p.K1023= | Silent (SNP) | VAF 49/129 reads (38%) | called by muse, mutect2, varscan2
- FBXL14 | c.1002G>A p.T334= | Silent (SNP) | VAF 40/106 reads (38%) | catalogued as COSV59336897; called by muse, mutect2, varscan2
- FGD5 | c.132G>A p.R44= | Silent (SNP) | VAF 40/120 reads (33%) | called by muse, mutect2, varscan2
- FIGN | c.720T>G p.S240= | Silent (SNP) | VAF 44/125 reads (35%) | called by muse, mutect2, varscan2
- FLG | c.2604G>A p.G868= | Silent (SNP) | VAF 66/197 reads (34%) | catalogued as rs771988615; called by muse, mutect2, varscan2
- FOXN1 | c.948G>A p.K316= | Silent (SNP) | VAF 37/100 reads (37%) | called by muse, mutect2, varscan2
- FRMPD3 | c.5115C>T p.T1705= | Silent (SNP) | VAF 44/69 reads (64%) | called by muse, mutect2, varscan2
- GPRC6A | c.993G>A p.G331= | Silent (SNP) | VAF 43/112 reads (38%) | catalogued as COSV59952721; called by muse, mutect2, varscan2
- GRB14 | c.1299C>T p.I433= | Silent (SNP) | VAF 30/75 reads (40%) | catalogued as rs900623186; called by muse, mutect2, varscan2
- GRIA3 | c.1980G>A p.R660= | Silent (SNP) | VAF 70/97 reads (72%) | catalogued as rs988146631; called by muse, mutect2, varscan2
- GSG1L | c.984G>A p.G328= (on ENST00000447459 / NM_001109763.2; = p.G173= on NM_144675.2) | Silent (SNP) | VAF 25/96 reads (26%) | called by muse, mutect2, varscan2
- GUCY2F | c.1077C>T p.I359= | Silent (SNP) | VAF 28/44 reads (64%) | catalogued as rs137951058, COSV54306471; called by muse, mutect2, varscan2
- HLX | c.603C>T p.S201= | Silent (SNP) | VAF 13/63 reads (21%) | called by muse, mutect2, varscan2
- HNRNPDL | c.1239C>T p.H413= | Silent (SNP) | VAF 34/101 reads (34%) | called by muse, mutect2, varscan2
- HSD17B14 | c.171C>T p.V57= | Silent (SNP) | VAF 26/63 reads (41%) | called by muse, mutect2, varscan2
- ISL1 | c.891C>T p.F297= | Silent (SNP) | VAF 37/112 reads (33%) | catalogued as rs754879931, COSV57933137; called by muse, mutect2, varscan2
- KCNJ3 | c.997T>C p.L333= | Silent (SNP) | VAF 43/120 reads (36%) | called by muse, mutect2, varscan2
- KCNV1 | c.474G>A p.R158= | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as rs548060083, COSV52089039; called by muse, mutect2, varscan2
- KIDINS220 | c.5097C>T p.F1699= | Silent (SNP) | VAF 16/155 reads (10%) | catalogued as rs750086954, COSV56750322, COSV56751823; called by muse, mutect2
- KLHL35 | c.1398G>A p.E466= | Silent (SNP) | VAF 26/75 reads (35%) | called by muse, mutect2, varscan2
- KRT77 | c.633G>A p.L211= | Silent (SNP) | VAF 26/72 reads (36%) | called by muse, mutect2, varscan2
- KRTAP19-8 | c.183C>T p.A61= | Silent (SNP) | VAF 39/105 reads (37%) | called by muse, mutect2, varscan2
- KRTAP27-1 | c.453C>T p.F151= | Silent (SNP) | VAF 41/129 reads (32%) | catalogued as rs781274963, COSV67000922; called by muse, mutect2, varscan2
- KSR1 | c.1185C>T p.F395= (on ENST00000644974 / NM_001367810.1; = p.F258= on NM_014238.2) | Silent (SNP) | VAF 21/99 reads (21%) | called by muse, mutect2, varscan2
- LBP | c.201G>A p.R67= | Silent (SNP) | VAF 42/126 reads (33%) | catalogued as COSV54140383; called by muse, mutect2, varscan2
- LCMT2 | c.774C>T p.F258= | Silent (SNP) | VAF 62/155 reads (40%) | called by muse, mutect2
- LIMA1 | c.2178C>T p.S726= | Silent (SNP) | VAF 43/111 reads (39%) | called by muse, mutect2, varscan2
- LIMCH1 | c.186G>A p.K62= | Silent (SNP) | VAF 27/93 reads (29%) | called by muse, mutect2, varscan2
- LMTK3 | c.2172C>T p.P724= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as rs1257957780; called by muse, mutect2, varscan2
- LPIN3 | c.678G>A p.S226= | Silent (SNP) | VAF 30/75 reads (40%) | catalogued as rs748696138; called by muse, mutect2, varscan2
- LRRIQ1 | c.954A>G p.A318= | Silent (SNP) | VAF 46/130 reads (35%) | called by muse, mutect2, varscan2
- MAEL | c.249G>A p.R83= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as rs983777069; called by muse, mutect2, varscan2
- MAP2 | c.4359C>G p.V1453= | Silent (SNP) | VAF 30/88 reads (34%) | catalogued as rs754444071; called by muse, mutect2, varscan2
- MED13 | c.5443T>C p.L1815= | Silent (SNP) | VAF 35/85 reads (41%) | catalogued as rs750521626; called by muse, mutect2, varscan2
- MEFV | c.123C>T p.P41= | Silent (SNP) | VAF 47/128 reads (37%) | called by muse, mutect2, varscan2
- MGAM2 | c.2241G>A p.R747= | Silent (SNP) | VAF 15/59 reads (25%) | called by muse, mutect2, varscan2
- MROH2B | c.1224G>A p.R408= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as rs1458431616; called by muse, mutect2, varscan2
- MSTO1 | c.1569G>A p.L523= | Silent (SNP) | VAF 30/110 reads (27%) | called by muse, mutect2
- MYO15B | c.7719G>A p.K2573= | Silent (SNP) | VAF 38/110 reads (35%) | called by muse, mutect2, varscan2
- MYO16 | c.30C>T p.S10= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as COSV51797163; called by muse, mutect2, varscan2
- MYO18B | c.3513G>A p.V1171= | Silent (SNP) | VAF 31/109 reads (28%) | called by muse, mutect2, varscan2
- NLRX1 | c.1780C>T p.L594= | Silent (SNP) | VAF 34/113 reads (30%) | called by muse, mutect2, varscan2
- NOMO2 | c.2148C>T p.A716= | Silent (SNP) | VAF 56/293 reads (19%) | called by muse, varscan2
- NPIPB5 | c.1719G>A p.K573= | Silent (SNP) | VAF 34/292 reads (12%) | called by muse, varscan2
- NPIPB6 | c.1131G>A p.R377= | Silent (SNP) | VAF 77/509 reads (15%) | catalogued as rs536416950; called by muse, mutect2, varscan2
- ONECUT1 | c.984G>T p.S328= | Silent (SNP) | VAF 67/177 reads (38%) | called by muse, mutect2, varscan2
- OR10AC1 | c.723C>T p.G241= | Silent (SNP) | VAF 44/123 reads (36%) | called by muse, mutect2, varscan2
- OR2T12 | c.873G>A p.R291= | Silent (SNP) | VAF 28/94 reads (30%) | catalogued as COSV58778220; called by muse, mutect2, varscan2
- OR4C16 | c.414C>T p.V138= | Silent (SNP) | VAF 58/159 reads (36%) | catalogued as COSV58941841; called by muse, mutect2, varscan2
- OR6B2 | c.282C>T p.F94= | Silent (SNP) | VAF 41/124 reads (33%) | catalogued as rs750021015, COSV53153142; called by muse, mutect2, varscan2
- P2RY6 | c.756C>T p.F252= | Silent (SNP) | VAF 40/100 reads (40%) | called by muse, mutect2, varscan2
- P2RY6 | c.757C>T p.L253= | Silent (SNP) | VAF 41/102 reads (40%) | called by muse, mutect2, varscan2
- PALM | c.21G>A p.E7= | Silent (SNP) | VAF 63/140 reads (45%) | called by muse, mutect2, varscan2
- PAX2 | c.1002G>A p.A334= (on ENST00000428433 / NM_003987.5; = p.A311= on NM_000278.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 34/124 reads (27%) | catalogued as rs755809967, COSV62292193; called by muse, mutect2, varscan2
- PCDHB11 | c.2178G>T p.S726= | Silent (SNP) | VAF 14/278 reads (5%) | catalogued as rs202157565, COSV100696935; called by muse, mutect2
- PCLO | c.5067A>C p.T1689= | Silent (SNP) | VAF 42/133 reads (32%) | called by muse, mutect2, varscan2
- PDE11A | c.1965G>A p.R655= | Silent (SNP) | VAF 35/93 reads (38%) | catalogued as rs202111041; called by muse, mutect2, varscan2
- PGR | c.426G>C p.L142= | Silent (SNP) | VAF 54/148 reads (36%) | called by muse, mutect2, varscan2
- PHB2 | c.444C>T p.F148= | Silent (SNP) | VAF 36/98 reads (37%) | called by muse, mutect2, varscan2
- PRSS41 | c.987C>T p.A329= | Silent (SNP) | VAF 26/80 reads (33%) | called by muse, mutect2, varscan2
- RBFOX2 | c.1071C>T p.V357= (on ENST00000438146 / NM_001349995.2; = p.V283= on NM_014309.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/146 reads (18%) | called by muse, mutect2, varscan2
- RCVRN | c.234C>T p.D78= | Silent (SNP) | VAF 52/152 reads (34%) | catalogued as rs937401965, COSV56841433; called by muse, mutect2, varscan2
- RELN | c.6846G>A p.L2282= | Silent (SNP) | VAF 56/175 reads (32%) | called by muse, mutect2, varscan2
- RHOBTB1 | c.498G>A p.G166= | Silent (SNP) | VAF 38/90 reads (42%) | called by muse, mutect2, varscan2
- RP1L1 | c.6075C>T p.A2025= | Silent (SNP) | VAF 65/204 reads (32%) | called by muse, mutect2, varscan2
- RYR1 | c.5214G>C p.T1738= | Silent (SNP) | VAF 34/102 reads (33%) | catalogued as COSV62099597; called by muse, mutect2, varscan2
- SCN2A | c.1965C>T p.S655= | Silent (SNP) | VAF 40/136 reads (29%) | catalogued as rs914170392, COSV99333955; ClinVar: likely benign; called by muse, mutect2, varscan2
- SEMA4B | c.1038C>T p.S346= | Silent (SNP) | VAF 38/86 reads (44%) | catalogued as COSV100202984; called by muse, mutect2, varscan2
- SEMA5A | c.1737C>T p.G579= | Silent (SNP) | VAF 47/147 reads (32%) | called by muse, mutect2, varscan2
- SHANK3 | c.4659G>A p.S1553= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as rs1479576199; called by muse, mutect2, varscan2
- SLC8A3 | c.2241C>T p.P747= (on ENST00000381269 / NM_183002.3; = p.P745= on NM_033262.4) | Silent (SNP) | VAF 54/174 reads (31%) | catalogued as rs760038494, COSV53688056, COSV53689021; called by muse, mutect2, varscan2
- SLU7 | c.1117C>T p.L373= | Silent (SNP) | VAF 35/72 reads (49%) | catalogued as rs1344219803; called by muse, mutect2, varscan2
- SLU7 | c.1116C>T p.I372= | Silent (SNP) | VAF 35/71 reads (49%) | called by muse, mutect2, varscan2
- SNCG | c.36G>A p.K12= | Silent (SNP) | VAF 41/106 reads (39%) | called by muse, mutect2, varscan2
- SOX11 | c.918G>A p.G306= | Silent (SNP) | VAF 35/100 reads (35%) | catalogued as rs774704629; called by muse, mutect2, varscan2
- SPTB | c.5718C>T p.F1906= | Silent (SNP) | VAF 31/91 reads (34%) | called by muse, mutect2, varscan2
- STRIP1 | c.762C>T p.S254= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as rs893218628; called by muse, mutect2, varscan2
- SULF2 | c.24G>A p.L8= | Silent (SNP) | VAF 37/93 reads (40%) | catalogued as rs1264389232; called by muse, mutect2, varscan2
- SYDE1 | c.438C>T p.A146= | Silent (SNP) | VAF 21/69 reads (30%) | called by muse, mutect2, varscan2
- SYT16 | c.100C>T p.L34= | Silent (SNP) | VAF 35/98 reads (36%) | called by muse, mutect2, varscan2
- TDRD15 | c.5616C>T p.F1872= | Silent (SNP) | VAF 27/100 reads (27%) | called by muse, mutect2, varscan2
- TENM3 | c.5253C>T p.F1751= | Silent (SNP) | VAF 36/104 reads (35%) | called by muse, mutect2, varscan2
- TONSL | c.2895C>T p.A965= | Silent (SNP) | VAF 47/134 reads (35%) | called by muse, mutect2, varscan2
- TRIM51 | c.420C>T p.L140= | Silent (SNP) | VAF 21/59 reads (36%) | called by muse, mutect2, varscan2
- TRMU | c.798G>A p.Q266= | Silent (SNP) | VAF 27/99 reads (27%) | called by muse, mutect2, varscan2
- TSPEAR | c.438C>T p.S146= | Silent (SNP) | VAF 55/160 reads (34%) | catalogued as COSV100554177; called by muse, varscan2
- TTC24 | c.1272C>T p.L424= | Silent (SNP) | VAF 40/134 reads (30%) | catalogued as COSV100964323, COSV63998042; called by muse, mutect2, varscan2
- UNC13C | c.1710C>T p.F570= | Silent (SNP) | VAF 27/88 reads (31%) | catalogued as COSV52850143; called by muse, mutect2, varscan2
- VGLL2 | c.675C>T p.A225= | Silent (SNP) | VAF 49/164 reads (30%) | called by muse, mutect2, varscan2
- WDR3 | c.180C>T p.I60= | Silent (SNP) | VAF 34/67 reads (51%) | catalogued as rs745944360; called by muse, mutect2, varscan2
- XIRP2 | c.9225T>C p.G3075= (on ENST00000628543; = p.G3250= on NM_152381.6) | Silent (SNP) | VAF 36/141 reads (26%) | called by muse, mutect2, varscan2
- ZAN | c.1188C>T p.A396= | Silent (SNP) | VAF 39/130 reads (30%) | called by muse, mutect2, varscan2
- ZBED4 | c.1848C>T p.V616= | Silent (SNP) | VAF 57/148 reads (39%) | called by muse, mutect2, varscan2
- ZDBF2 | c.4821G>A p.K1607= | Silent (SNP) | VAF 45/122 reads (37%) | catalogued as COSV65630912; called by muse, mutect2, varscan2
- ZDHHC18 | c.90C>T p.S30= | Silent (SNP) | VAF 5/10 reads (50%) | called by mutect2, varscan2
- ZFYVE28 | c.1579C>T p.L527= | Silent (SNP) | VAF 46/138 reads (33%) | catalogued as COSV99343005; called by muse, mutect2, varscan2
- ZNF16 | c.429C>T p.L143= | Silent (SNP) | VAF 32/107 reads (30%) | called by muse, mutect2, varscan2
- ZNF483 | c.1836C>T p.C612= | Silent (SNP) | VAF 40/131 reads (31%) | catalogued as rs759377638, COSV58515327; called by muse, mutect2, varscan2
- AC087379.2 | n.498G>A | RNA (SNP) | VAF 35/109 reads (32%) | called by muse, mutect2, varscan2
- ADK | c.*116T>A | 3'UTR (SNP) | VAF 13/41 reads (32%) | called by muse, mutect2, varscan2
- AL450447.1 | n.154C>T | RNA (SNP) | VAF 28/81 reads (35%) | catalogued as rs1332678520; called by muse, mutect2, varscan2
- AL450447.1 | n.153C>T | RNA (SNP) | VAF 28/81 reads (35%) | called by muse, mutect2, varscan2
- DIP2C | c.85+26659T>A | Intron (SNP) | VAF 68/156 reads (44%) | called by muse, mutect2, varscan2
- DNAH12 | c.6930-5114A>G | Intron (SNP) | VAF 31/76 reads (41%) | called by muse, mutect2, varscan2
- FAM124A | c.834+39G>A | Intron (SNP) | VAF 30/86 reads (35%) | called by muse, varscan2
- GABRG3 | c.712+44G>A | Intron (SNP) | VAF 26/77 reads (34%) | catalogued as rs1454129418, COSV100403520; called by muse, mutect2, varscan2
- GABRG3 | c.712+45G>A | Intron (SNP) | VAF 26/76 reads (34%) | catalogued as rs1306393605; called by muse, mutect2, varscan2
- KIAA1958 | c.1172-27713C>T | Intron (SNP) | VAF 54/136 reads (40%) | catalogued as COSV61724346; called by muse, varscan2
- KIAA1958 | c.1172-27712C>T | Intron (SNP) | VAF 55/134 reads (41%) | catalogued as rs1036946589; called by muse, mutect2, varscan2
- MAMLD1 | c.*21C>T | 3'UTR (SNP) | VAF 54/61 reads (89%) | called by muse, mutect2, varscan2
- MUC15 | chr11:26572174 G>T | 5'Flank (SNP) | VAF 53/110 reads (48%) | called by muse, mutect2, varscan2
- MUC19 | n.18645G>A | RNA (SNP) | VAF 31/79 reads (39%) | called by muse, mutect2, varscan2
- NFASC | c.-28G>A | 5'UTR (SNP) | VAF 47/128 reads (37%) | catalogued as rs1422391125; called by muse, mutect2, varscan2
- NUGGC | c.149-45_149-35del | Intron (DEL) | VAF 24/50 reads (48%) | called by mutect2, pindel, varscan2
- OR2S1P | n.273-9601G>T | Intron (SNP) | VAF 58/136 reads (43%) | catalogued as rs1178755277; called by mutect2, varscan2
- P2RY6 | c.-232T>C | 5'UTR (SNP) | VAF 42/133 reads (32%) | called by muse, mutect2, varscan2
- SCYL2 | chr12:100267142 G>A | 5'Flank (SNP) | VAF 33/87 reads (38%) | catalogued as rs906735229; called by muse, mutect2, varscan2
- SSPOP | n.15767C>T | RNA (SNP) | VAF 23/64 reads (36%) | catalogued as rs1460070417; called by muse, mutect2, varscan2
- SSUH2 | c.-3-591G>A | Intron (SNP) | VAF 48/127 reads (38%) | catalogued as rs761089081; called by muse, mutect2, varscan2
- TCFL5 | c.1381-3906C>T | Intron (SNP) | VAF 52/138 reads (38%) | called by muse, mutect2, varscan2
- TCP10L2 | n.274C>T | RNA (SNP) | VAF 24/87 reads (28%) | catalogued as rs1433414222; called by muse, mutect2, varscan2
